Somatic mutation profile of tumor specimen TCGA-E7-A4IJ-01A (aliquot TCGA-E7-A4IJ-01A-31D-A26M-08) from TCGA case TCGA-E7-A4IJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.7 years (20,723 days).
Specimen TCGA-E7-A4IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ac614e4-d518-48f3-bc63-977decabf979.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A4IJ-10A (Blood Derived Normal), aliquot TCGA-E7-A4IJ-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b58e1b7-e4c6-4ced-91fc-cc6be789b76f

The open-access MAF lists 388 somatic variants for this specimen: 272 protein-altering or splice-affecting, 107 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 238, Silent 107, Nonsense Mutation 19, Splice Site 6, Intron 4, Frame Shift Del 4, Splice Region 2, 3'Flank 2, RNA 2, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC14A | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs549556142, COSV60556075; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 52/94 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/31 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TUFM | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121434452, CM071117, COSV57949901; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ADAM30 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as rs1037978740, COSV65560937; called by muse, mutect2, varscan2
- ADGRV1 | c.4040C>G p.S1347C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV67996484; called by muse, mutect2, varscan2
- ADRA1D | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101063134; called by muse, mutect2, varscan2
- AGPAT4 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100212021; called by muse, mutect2, varscan2
- AHNAK | c.6579G>C p.L2193F | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57230143; called by muse, mutect2, varscan2
- AKAP9 | c.9118C>G p.H3040D (on ENST00000359028; = p.H3016D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV62344977, COSV62359066; called by muse, mutect2, varscan2
- AKR1E2 | c.951C>A p.H317Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV53632113; called by muse, mutect2, varscan2
- ANKH | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV52487092; called by muse, mutect2, varscan2
- ANO2 | c.2150C>G p.S717C (on ENST00000356134 / NM_001278597.3; = p.S721C on NM_001278596.3) | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as COSV59045595; called by muse, mutect2, varscan2
- AP3B1 | c.3197C>G p.S1066C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs764100439, COSV54894237; called by muse, mutect2, varscan2
- ARID1B | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51683016; called by muse, mutect2, varscan2
- ARID1B | c.4165G>C p.E1389Q | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV51683031; called by muse, mutect2, varscan2
- ARL14 | c.419T>C p.F140S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57900569; called by muse, mutect2, varscan2
- ATP6V0A2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs144949442, COSV100376760; called by muse, mutect2, varscan2
- ATP6V1B1 | c.919G>C p.A307P | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52272433; called by muse, mutect2, varscan2
- BAIAP3 | c.1825C>A p.Q609K | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV50105864; called by muse, mutect2
- BIN1 | c.1773G>T p.R591S (on ENST00000316724 / NM_001320642.1; = p.R452S on NM_004305.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV52122533; called by muse, mutect2, varscan2
- BUD13 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52768297; called by muse, mutect2, varscan2
- BUD23 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.474); catalogued as COSV56096532; called by muse, mutect2, varscan2
- C10orf88 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV64403595, COSV64403852; called by mutect2, varscan2
- C12orf50 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100072489; called by muse, mutect2
- C3orf56 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV101228983, COSV67756072; called by muse, mutect2, varscan2
- C5orf34 | c.1159G>C p.E387Q | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV60932250; called by muse, mutect2, varscan2
- CACNA1E | c.6517A>C p.S2173R (on ENST00000367573 / NM_001205293.3; = p.S2130R on NM_000721.4) | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.422); catalogued as COSV62432385; called by muse, mutect2, varscan2
- CACNB1 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV60000561; called by muse, mutect2, varscan2
- CACNB2 | c.512G>A p.G171E (on ENST00000324631 / NM_201596.3; = p.G116E on NM_000724.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649655; called by muse, mutect2, varscan2
- CACNG7 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs1168996008, COSV55817615; called by muse, mutect2, varscan2
- CASC3 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as rs1424853364, COSV52869625; called by muse, mutect2, varscan2
- CBX6 | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV53322197; called by muse, mutect2, varscan2
- CCDC178 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as rs1270739738, COSV100286616; called by muse, mutect2
- CEP192 | c.5081C>T p.S1694L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58071314; called by muse, mutect2, varscan2
- CEP68 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 61/93 reads (66%) | catalogued as COSV99561250; called by muse, mutect2, varscan2
- CHSY1 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54256340; called by muse, mutect2, varscan2
- CLEC14A | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60563444; called by muse, mutect2, varscan2
- CLIP1 | c.1753C>A p.Q585K (on ENST00000620786 / NM_001247997.1; = p.Q574K on NM_002956.2) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as COSV56809361; called by muse, mutect2, varscan2
- CLSTN2 | c.2798G>A p.R933K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101515917; called by muse, mutect2
- COG1 | c.2533C>G p.L845V | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55432279; called by muse, mutect2, varscan2
- COL22A1 | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV57363315; called by muse, mutect2, varscan2
- COL4A2 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.089); catalogued as COSV64635073; called by muse, mutect2, varscan2
- CPLANE1 | c.8885G>A p.R2962Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1264659510, COSV57075901; called by muse, mutect2, varscan2
- CR1L | c.575G>C p.R192T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV54332033; called by muse, mutect2, varscan2
- CRISPLD1 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1159162206, COSV51553521; called by muse, mutect2, varscan2
- CSPP1 | c.244T>A p.L82M (on ENST00000676605; = p.L41M on NM_024790.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51593413; called by muse, mutect2, varscan2
- CST8 | c.299G>C p.S100T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV55672253; called by muse, mutect2, varscan2
- CTNNA3 | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV65530397; called by mutect2, varscan2
- CTNNB1 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV62723797; called by muse, mutect2, varscan2
- CYYR1 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54838469; called by muse, mutect2
- DALRD3 | c.727G>A p.D243N (on ENST00000341949 / NM_001009996.3; = p.D76N on NM_018114.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as rs756920547, COSV58247792; called by muse, mutect2, varscan2
- DCBLD1 | c.1232G>C p.G411A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51646726; called by muse, mutect2, varscan2
- DDX1 | c.1875+1G>A p.X625_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as rs1336065219, COSV51843920; called by muse, mutect2, varscan2
- DHX30 | c.1602C>G p.F534L (on ENST00000445061 / NM_138615.3; = p.F495L on NM_014966.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV53135945, COSV53143426; called by muse, mutect2, varscan2
- DIP2A | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs768631143, COSV59488044; called by muse, mutect2, varscan2
- DLC1 | c.3783A>T p.K1261N (on ENST00000276297 / NM_001348081.2; = p.K824N on NM_006094.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV52330348; called by muse, mutect2, varscan2
- DMXL1 | c.8884C>G p.L2962V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.577); catalogued as COSV60722105; called by muse, mutect2, varscan2
- DNAAF1 | c.1973A>G p.Q658R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs568725470, COSV58989679; called by muse, mutect2, varscan2
- DNAH17 | c.12115G>C p.E4039Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67761926; called by muse, mutect2, varscan2
- DNAJC1 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775518409, COSV65414334; called by muse, mutect2, varscan2
- DNMT3A | c.2481C>T p.F827= | Splice Region (SNP) | VAF 18/49 reads (37%) | catalogued as COSV53038999, COSV53080851; called by muse, mutect2, varscan2
- DPY19L2 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60541119, COSV60543766; called by mutect2, varscan2
- DSG3 | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV57130114; called by muse, mutect2, varscan2
- DST | c.9226G>A p.D3076N | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.022); catalogued as COSV55043417; called by muse, mutect2, varscan2
- DST | c.8885G>A p.G2962E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV55037371; called by muse, mutect2
- DST | c.8572G>T p.E2858* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99759711; called by muse, varscan2
- DST | c.8506G>A p.E2836K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.048); catalogued as COSV55043425; called by muse, varscan2
- DYRK1A | c.2029A>T p.N677Y | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.979); catalogued as COSV58710692; called by muse, mutect2
- EI24 | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54021424; called by muse, mutect2, varscan2
- EIF3B | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100703850; called by muse, mutect2, varscan2
- EIF4E3 | c.582C>G p.I194M (on ENST00000425534 / NM_001134651.2; = p.I88M on NM_173359.5) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1359570883, COSV55207298; called by muse, mutect2, varscan2
- EXOC4 | c.1393T>A p.Y465N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as rs1204619737, COSV54125330; called by muse, mutect2, varscan2
- EYA1 | c.194C>G p.S65* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100380238, COSV58159511; called by muse, mutect2, varscan2
- FANK1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV64136363, COSV64138048; called by muse, mutect2, varscan2
- FAT1 | c.8669C>G p.S2890* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV71671643, COSV71675563; called by mutect2, varscan2
- FAT1 | c.2989T>C p.Y997H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV71676220; called by muse, mutect2, varscan2
- FBXL19 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57945889; called by muse, mutect2, varscan2
- FBXL7 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as COSV100310755; called by muse, mutect2, varscan2
- FCGR2A | c.529G>T p.A177S (on ENST00000271450 / NM_001136219.3; = p.A176S on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54841078; called by muse, mutect2, varscan2
- FGFR1 | c.2392C>T p.H798Y (on ENST00000447712 / NM_023110.3; = p.H796Y on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV58345537; called by muse, mutect2, varscan2
- FMNL3 | c.1173G>C p.K391N | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53308413; called by muse, mutect2, varscan2
- FRMPD2 | c.2371A>C p.N791H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.876); catalogued as COSV100564157; called by muse, mutect2
- GADD45GIP1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.778); catalogued as COSV57539877; called by muse, mutect2, varscan2
- GBP4 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as COSV100864458; called by muse, mutect2, varscan2
- GBP4 | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV100864429, COSV100864459; called by muse, mutect2, varscan2
- GEMIN5 | c.2630G>A p.R877K | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53565426; called by muse, mutect2, varscan2
- GET3 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV54407676, COSV54407689; called by muse, mutect2, varscan2
- GFRA1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100816109; called by muse, mutect2
- GPX7 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV63652973; called by muse, mutect2, varscan2
- GUCY1B1 | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV52379467; called by muse, mutect2, varscan2
- H2AC12 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV63617762; called by muse, mutect2
- HADHB | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58546529, COSV58548869; called by muse, mutect2, varscan2
- HERC2 | c.12734G>C p.G4245A | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV55352704; called by muse, mutect2, varscan2
- HIPK2 | c.3409C>G p.P1137A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV101301660; called by muse, mutect2, varscan2
- HP1BP3 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV56563380, COSV56565002; called by muse, mutect2, varscan2
- HSPB9 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs533835701, COSV56793142; called by muse, mutect2
- HYLS1 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV54993018; called by muse, mutect2, varscan2
- ICA1L | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377105465, COSV64175499; called by muse, mutect2, varscan2
- IFI44 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.82); PolyPhen benign (0.061); catalogued as COSV66075900; called by muse, mutect2, varscan2
- IFT43 | c.296-1G>T p.X99_splice (on ENST00000314067 / NM_001102564.3; = p.X104_splice on NM_052873.3) | Splice Site (SNP) | VAF 107/153 reads (70%) | catalogued as COSV53141874; called by muse, mutect2, varscan2
- IGF2R | c.4338G>C p.W1446C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100808127; called by muse, mutect2
- IGSF3 | c.3161G>A p.R1054H (on ENST00000369486 / NM_001007237.3; = p.R1074H on NM_001542.4) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs553592752, COSV59590184, COSV59595226; called by muse, mutect2
- IL17RC | c.1605C>G p.I535M (on ENST00000295981 / NM_153461.4; = p.I449M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as rs145526460; called by muse, mutect2, varscan2
- INHBE | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.429); catalogued as rs917627123, COSV99875368; called by muse, mutect2, varscan2
- IRS2 | c.633G>C p.K211N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV65478755, COSV65481070; called by muse, mutect2, varscan2
- ITGAV | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53719659; called by muse, mutect2, varscan2
- ITPR2 | c.4742C>G p.S1581* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101190149; called by muse, mutect2, varscan2
- JAK2 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67665325, COSV67674949; called by muse, mutect2, varscan2
- JARID2 | c.2674C>T p.L892F | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59199121, COSV59199475; called by muse, mutect2, varscan2
- KANSL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52274763; called by mutect2, varscan2
- KATNIP | c.3199C>A p.P1067T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV55193093; called by muse, mutect2, varscan2
- KIF20B | c.4369G>T p.A1457S (on ENST00000371728 / NM_001284259.2; = p.A1417S on NM_016195.4) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV53316327; called by muse, mutect2, varscan2
- KIF4B | c.2510T>A p.L837Q | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV70531839; called by muse, mutect2, varscan2
- KPNB1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV51600979; called by muse, mutect2
- KRT71 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57293352; called by muse, mutect2, varscan2
- LAMA3 | c.5813A>G p.K1938R (on ENST00000313654 / NM_198129.4; = p.K329R on NM_000227.6) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.767); catalogued as rs1237495784, COSV52544404; called by muse, mutect2, varscan2
- LOXL2 | c.1064G>A p.W355* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV101207983; called by muse, mutect2, varscan2
- LRRC14 | c.817T>G p.F273V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV52877783, COSV52883170; called by muse, mutect2, varscan2
- LRRC7 | c.3139A>T p.T1047S (on ENST00000651989 / NM_001370785.2; = p.T1014S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV50645712; called by muse, mutect2, varscan2
- LTV1 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62536169, COSV62536796; called by muse, mutect2, varscan2
- MAPK6 | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV55931945; called by muse, mutect2, varscan2
- MBD5 | c.2001G>C p.L667F | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.391); catalogued as COSV68698430; called by muse, mutect2, varscan2
- MED14 | c.2951C>A p.P984H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61358801; called by muse, mutect2, varscan2
- MEGF8 | c.7817C>T p.A2606V (on ENST00000251268 / NM_001271938.2; = p.A2539V on NM_001410.3) | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52103558; called by muse, mutect2
- MGRN1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.048); catalogued as rs762339568, COSV52154923; called by muse, mutect2, varscan2
- MUC16 | c.37956C>A p.D12652E | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.959); catalogued as rs1244458467, COSV67498142; called by muse, mutect2, varscan2
- MUC17 | c.9895A>G p.S3299G | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.24); catalogued as rs1301395849, COSV60305790; called by muse, mutect2, varscan2
- MUC17 | c.12409G>A p.G4137R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV60279027; called by muse, mutect2, varscan2
- MYLK2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.443); catalogued as COSV65660089; called by muse, mutect2, varscan2
- MYO5B | c.1752+1G>T p.X584_splice | Splice Site (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53232872; called by muse, mutect2, varscan2
- NAV3 | c.5905G>C p.D1969H (on ENST00000397909 / NM_001024383.2; = p.D1947H on NM_014903.6) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57115224; called by muse, mutect2, varscan2
- NCKAP5 | c.5224C>G p.P1742A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV58478302; called by muse, mutect2, varscan2
- NCKAP5L | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100259191; called by muse, varscan2
- NCKAP5L | c.1333C>G p.Q445E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV60134532; called by muse, mutect2, varscan2
- NCKAP5L | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV60134550; called by muse, mutect2, varscan2
- NEB | c.5723G>A p.S1908N | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV99427673; called by muse, mutect2
- NETO1 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV55014478; called by muse, mutect2, varscan2
- NKX2-2 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65820455; called by muse, mutect2
- NLRP14 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 28/34 reads (82%) | catalogued as rs373865085, COSV100205215, COSV55065906; called by muse, mutect2, varscan2
- NOTCH3 | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54625102, COSV99658729; called by muse, mutect2
- NOX5 | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294373869, COSV52996926; called by muse, mutect2, varscan2
- NR0B1 | c.315G>C p.W105C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs132630327, CM071045, CM148123, COSV66764909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSG2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100292941; called by muse, mutect2, varscan2
- NSMCE1 | c.196T>A p.S66T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63864911; called by muse, mutect2, varscan2
- NUP205 | c.4748C>G p.A1583G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV53666899; called by muse, mutect2, varscan2
- NYNRIN | c.3163G>C p.D1055H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV66845463; called by muse, mutect2, varscan2
- OBSCN | c.15264C>G p.I5088M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV52836441; called by muse, mutect2, varscan2
- OR13A1 | c.775T>A p.C259S | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65573597; called by muse, mutect2
- OR2T27 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs528356076, COSV61282221; called by muse, mutect2, varscan2
- OR4D11 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57587372; called by muse, mutect2, varscan2
- OR52B4 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101281606, COSV68768684; called by muse, mutect2
- OR8B2 | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100899500, COSV66665594; called by muse, mutect2, varscan2
- OR9G1 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56454548; called by muse, mutect2, varscan2
- OSTC | c.408A>T p.R136S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.783); catalogued as COSV64232553; called by muse, mutect2, varscan2
- PAK5 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs559966028, COSV62025299, COSV62039210; called by muse, mutect2, varscan2
- PAPPA2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV62776320, COSV62787804; called by muse, mutect2
- PBRM1 | c.4149G>C p.M1383I (on ENST00000296302 / NM_001366071.2; = p.M1331I on NM_018313.5) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV56308045; called by muse, mutect2, varscan2
- PCBP4 | c.387+3G>A | Splice Region (SNP) | VAF 30/79 reads (38%) | catalogued as COSV59056423; called by muse, mutect2, varscan2
- PCDHA7 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as COSV65348033; called by muse, mutect2, varscan2
- PCDHB5 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.17); catalogued as COSV50675877; called by muse, mutect2, varscan2
- PCLO | c.10948G>A p.D3650N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV100437512, COSV61629923; called by muse, mutect2, varscan2
- PCLO | c.8997A>C p.L2999F | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV61671684; called by muse, mutect2, varscan2
- PDZK1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61092863; called by muse, mutect2, varscan2
- PIGC | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV51131178; called by muse, mutect2, varscan2
- PKD1L1 | c.8257A>G p.R2753G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1562933424, COSV51845412; called by muse, mutect2, varscan2
- PKD1L2 | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 69/102 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV61420206; called by muse, mutect2, varscan2
- PKDREJ | c.6237G>C p.Q2079H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs138967620, COSV53553645; called by muse, mutect2
- PKHD1L1 | c.11464G>A p.V3822M | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV65754708; called by muse, mutect2, varscan2
- PLIN4 | c.3208C>T p.P1070S (on ENST00000301286; = p.P1085S on NM_001367868.2) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV56699648; called by muse, mutect2, varscan2
- PLVAP | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53088017; called by muse, mutect2, varscan2
- PNKD | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV50309831; called by muse, mutect2, varscan2
- POLR1G | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV50005651; called by muse, mutect2, varscan2
- PRB4 | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as rs1477340918, COSV54400570, COSV99686874; called by muse, mutect2
- PREP | c.1672G>A p.E558K (on ENST00000369110; = p.E624K on NM_002726.5) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as COSV64872437; called by muse, mutect2, varscan2
- PRPF40B | c.586C>A p.Q196K (on ENST00000380281; = p.Q190K on NM_012272.3) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.292); catalogued as COSV56060812, COSV56062131; called by muse, mutect2, varscan2
- PRRG2 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV55871927, COSV55871973; called by muse, mutect2, varscan2
- PRUNE1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54960192; called by muse, mutect2, varscan2
- PTPRE | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV54556311, COSV54559902; called by muse, mutect2
- RAB3IL1 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 106/172 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs1343579864, COSV57119161; called by muse, mutect2, varscan2
- RAPGEF2 | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52426395; called by muse, mutect2, varscan2
- RBM6 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV56488731; called by muse, mutect2, varscan2
- RGS12 | c.2797G>C p.E933Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58752804, COSV58752996; called by muse, mutect2
- RGS9 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52229839; called by muse, mutect2
- RIMKLB | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.36); catalogued as COSV55240383; called by muse, mutect2, varscan2
- RIN1 | c.1897C>G p.Q633E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV60929110; called by muse, mutect2, varscan2
- RIOK3 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.597); catalogued as COSV59775338; called by muse, mutect2, varscan2
- RIPK4 | c.1412T>A p.M471K (on ENST00000352483; = p.M423K on NM_020639.3) | Missense Mutation (SNP) | VAF 201/390 reads (52%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.781); catalogued as COSV60191730; called by muse, mutect2, varscan2
- RLF | c.5242G>C p.E1748Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV65653370; called by muse, mutect2, varscan2
- RNF114 | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV54871178; called by muse, mutect2, varscan2
- RNF13 | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV60133885; called by muse, mutect2
- RNF17 | c.4583+1G>T p.X1528_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99694372; called by muse, mutect2
- RNF213 | c.6327G>T p.R2109S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV60404095, COSV60410187; called by muse, mutect2, varscan2
- RRBP1 | c.3257T>C p.L1086P (on ENST00000377813 / NM_001365613.2; = p.L653P on NM_004587.3) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55709462; called by muse, mutect2, varscan2
- RRN3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV52213781; called by muse, mutect2, varscan2
- RUBCN | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs1268950805, COSV56363953, COSV56375254; called by muse, mutect2, varscan2
- RYR1 | c.14406G>T p.L4802F | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV62112492; called by muse, mutect2, varscan2
- SCN1A | c.4554A>C p.K1518N (on ENST00000303395 / NM_001202435.3; = p.K1507N on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CD096221, COSV57690139; called by muse, mutect2, varscan2
- SCN3A | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV51826178; called by muse, mutect2, varscan2
- SEMA3E | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57110901; called by muse, mutect2, varscan2
- SH3BP4 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs770090403, COSV60646812; called by mutect2, varscan2
- SH3RF2 | c.1556-1G>C p.X519_splice | Splice Site (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100768094, COSV63041589; called by muse, mutect2, varscan2
- SHB | c.766C>G p.L256V | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT tolerated (0.58); PolyPhen benign (0.073); catalogued as COSV66622214; called by muse, mutect2, varscan2
- SKAP1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs116549994, COSV61153337; called by muse, mutect2
- SLC14A1 | c.1037C>T p.T346M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1377322159, COSV58934662; called by muse, mutect2, varscan2
- SLC22A10 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60423269; called by muse, mutect2, varscan2
- SLC24A1 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.035); catalogued as COSV56054447; called by muse, mutect2, varscan2
- SLC35G6 | c.454_463del p.Q152Vfs*13 | Frame Shift Del (DEL) | VAF 99/174 reads (57%) | catalogued as COSV59496622; called by mutect2, pindel, varscan2
- SLC38A4 | c.1619A>T p.D540V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV56966864, COSV56971816; called by muse, mutect2, varscan2
- SLC39A6 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52371679; called by muse, mutect2, varscan2
- SLC45A4 | c.856G>A p.E286K (on ENST00000517878 / NM_001286646.2; = p.E235K on NM_001080431.2) | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as rs756263729, COSV50196754; called by muse, mutect2, varscan2
- SLIT1 | c.2118G>C p.Q706H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56600394; called by mutect2, varscan2
- SMIM7 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV51818787; called by muse, mutect2
- SMTN | c.1785G>A p.M595I | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60783572; called by muse, mutect2, varscan2
- SNX19 | c.2157G>T p.K719N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56289373; called by muse, mutect2, varscan2
- SORCS1 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99550066; called by muse, mutect2, varscan2
- SP6 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV60617102; called by muse, mutect2, varscan2
- SRARP | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV61498123; called by muse, mutect2, varscan2
- SSH2 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV52182350; called by muse, mutect2, varscan2
- STAG2 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as COSV54356717, COSV54365939, COSV54376336; called by muse, mutect2, varscan2
- SUGP2 | c.695A>C p.Q232P | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV58266177; called by muse, mutect2, varscan2
- SYNPO2 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as COSV61118512; called by muse, varscan2
- TBC1D1 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV54728214; called by muse, mutect2, varscan2
- TECR | c.533A>C p.Y178S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53109334; called by muse, mutect2, varscan2
- TENM3 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as COSV69320962; called by muse, mutect2, varscan2
- TMCO4 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53877885; called by muse, mutect2, varscan2
- TOMM70 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.028); catalogued as COSV52525974; called by muse, mutect2, varscan2
- TP53 | c.492del p.K164Nfs*6 | Frame Shift Del (DEL) | VAF 26/44 reads (59%) | catalogued as COSV53165155, COSV53219732, COSV53700637; called by mutect2, varscan2
- TRAPPC9 | c.323C>G p.S108C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66910507; called by muse, mutect2, varscan2
- TRPA1 | c.2846C>G p.P949R | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418865582, COSV51575467; called by muse, mutect2, varscan2
- TSPYL5 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV59073034; called by muse, mutect2, varscan2
- TTC16 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV60162316; called by muse, mutect2, varscan2
- TTI1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV65063971; called by muse, mutect2, varscan2
- TTLL7 | c.2192C>T p.S731F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53089551; called by muse, mutect2, varscan2
- TTN | c.95029G>A p.D31677N (on ENST00000591111; = p.D24253N on NM_003319.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen probably damaging (0.951); catalogued as COSV60384267; called by muse, mutect2, varscan2
- TTN | c.75742T>C p.Y25248H (on ENST00000591111; = p.Y17824H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | PolyPhen probably damaging (0.919); catalogued as COSV60384300; called by muse, mutect2, varscan2
- TTN | c.25382G>A p.R8461K (on ENST00000591111; = p.R7534K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | PolyPhen probably damaging (0.967); catalogued as COSV60384329; called by muse, mutect2, varscan2
- TTN | c.16928C>T p.S5643L (on ENST00000591111; = p.S4716L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | PolyPhen benign (0); catalogued as COSV60384340; called by muse, mutect2, varscan2
- ULK1 | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs1390615388, COSV58860277; called by muse, mutect2, varscan2
- UMOD | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs368993197; called by muse, mutect2, varscan2
- UNC13C | c.2356G>C p.D786H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99522726; called by muse, mutect2
- USP11 | c.2203G>A p.E735K (on ENST00000218348; = p.E692K on NM_001371072.1) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.85); PolyPhen benign (0.179); catalogued as COSV54475648; called by muse, mutect2, varscan2
- UVSSA | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as COSV66231106; called by muse, mutect2, varscan2
- VDR | c.581C>G p.S194* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99968970; called by muse, mutect2, varscan2
- VNN2 | c.1371+1G>T p.X457_splice | Splice Site (SNP) | VAF 9/18 reads (50%) | catalogued as COSV58474628; called by muse, mutect2, varscan2
- VPS50 | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs368407161; called by muse, mutect2, varscan2
- VPS8 | c.748A>G p.I250V (on ENST00000625842 / NM_001349294.1; = p.I248V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54997687; called by muse, mutect2, varscan2
- VWCE | c.1845C>G p.I615M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57115840; called by muse, mutect2, varscan2
- ZEB1 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV58056176; called by muse, mutect2, varscan2
- ZFHX3 | c.5563C>G p.Q1855E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV51738595; called by muse, mutect2, varscan2
- ZFP28 | c.415C>G p.L139V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56738440; called by muse, mutect2, varscan2
- ZFYVE9 | c.4124A>G p.Y1375C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs769454524, COSV55101114; called by muse, mutect2, varscan2
- ZMIZ1 | c.3035C>G p.S1012* | Nonsense Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV100566529; called by muse, mutect2, varscan2
- ZNF208 | c.1734G>C p.E578D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101237196; called by muse, mutect2
- ZNF366 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV59219464; called by muse, mutect2, varscan2
- ZNF366 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV59214242, COSV59219472; called by muse, mutect2, varscan2
- ZNF518B | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1392690758, COSV58725065; called by muse, mutect2, varscan2
- ZNF570 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV57581048; called by muse, mutect2, varscan2
- ZNF665 | c.1506G>T p.E502D (on ENST00000600412; = p.E567D on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV67217899; called by muse, mutect2, varscan2
- ZNF667 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs776472792, COSV52631654; called by mutect2, varscan2
- ZNF785 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV67876650; called by muse, mutect2, varscan2
- ZNF787 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54417695; called by muse, mutect2, varscan2
- ZNF85 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100059879, COSV100060131; called by muse, mutect2
- ZNF91 | c.2933C>T p.S978F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.369); catalogued as rs1011015722, COSV56094319; called by muse, mutect2, varscan2
- ASAP1 | c.626del p.K209Rfs*33 | Frame Shift Del (DEL) | VAF 9/104 reads (9%) | called by mutect2, pindel*
- NME1 | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2
- PPIG | c.345_346dup p.G116Efs*12 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- REPS2 | c.658_668del p.E220Sfs*5 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- SMARCD1 | c.363_365dup p.N122dup | In Frame Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- SPATA31A3 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); called by muse, mutect2
- ZNF26 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA4 | c.1164G>A p.R388= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV64678829; called by muse, mutect2, varscan2
- ABCA8 | c.4674G>A p.Q1558= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52213428; called by muse, mutect2, varscan2
- ABCC2 | c.3960C>T p.I1320= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV64988819; called by muse, mutect2, varscan2
- ACKR3 | c.873C>T p.H291= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs370632662; called by muse, mutect2, varscan2
- ADAMTS19 | c.1959A>T p.R653= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV50805591; called by muse, mutect2, varscan2
- ADCY8 | c.934C>A p.R312= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV53913858, COSV53930456; called by muse, mutect2, varscan2
- ANKEF1 | c.2280G>A p.Q760= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV65693917; called by muse, mutect2, varscan2
- ARHGAP31 | c.3039G>T p.L1013= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV51800022; called by muse, mutect2, varscan2
- ATL1 | c.1215G>T p.V405= | Silent (SNP) | VAF 29/37 reads (78%) | catalogued as COSV63297814, COSV63297833; called by muse, mutect2, varscan2
- ATP13A4 | c.2812C>T p.L938= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as COSV61328308; called by muse, mutect2, varscan2
- C1orf87 | c.249G>T p.V83= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV64599090; called by muse, mutect2
- CACNA1D | c.4230G>A p.E1410= (on ENST00000350061 / NM_001128840.3; = p.E1430= on NM_000720.4) | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV55442545; called by muse, mutect2, varscan2
- CD300LG | c.336G>C p.R112= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV53226059; called by muse, mutect2, varscan2
- CEP112 | c.531A>G p.R177= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV101211127; called by muse, mutect2
- CLVS1 | c.324C>T p.F108= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57981197, COSV57983943; called by muse, mutect2, varscan2
- COLGALT1 | c.1332C>T p.F444= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV53111756; called by muse, mutect2, varscan2
- COLQ | c.1367G>A p.*456= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV101082508, COSV67525190; called by muse, mutect2, varscan2
- CRNN | c.477T>A p.T159= | Silent (SNP) | VAF 82/246 reads (33%) | catalogued as COSV55124176; called by muse, mutect2, varscan2
- CRTC2 | c.87G>A p.Q29= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs983583894, COSV57841150; called by muse, mutect2, varscan2
- CT45A1 | c.108G>A p.L36= | Silent (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- DEUP1 | c.1814G>A p.*605= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV99977611; called by muse, mutect2, varscan2
- DNAH8 | c.10404C>G p.L3468= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as COSV59484164; called by muse, mutect2, varscan2
- DPP6 | c.2460G>A p.P820= (on ENST00000377770 / NM_001364500.2; = p.P758= on NM_001936.5) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs778573229, COSV59648284; called by muse, mutect2, varscan2
- EFCAB6 | c.3123G>A p.K1041= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV53065097; called by muse, mutect2
- EPPK1 | c.4407C>G p.L1469= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV73262440; called by muse, mutect2, varscan2
- FAM102B | c.180C>T p.F60= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV64239481; called by muse, mutect2, varscan2
- FAM135B | c.3732G>T p.L1244= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV52756318; called by muse, mutect2, varscan2
- FCRL2 | c.609T>C p.S203= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as COSV63835324; called by muse, mutect2
- FCSK | c.1014C>G p.L338= | Silent (SNP) | VAF 68/133 reads (51%) | catalogued as COSV55375989; called by muse, mutect2, varscan2
- FLII | c.753C>G p.L251= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV58948460; called by muse, mutect2, varscan2
- FLNB | c.7356C>T p.I2452= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV55898048; called by muse, mutect2, varscan2
- GALNT8 | c.180C>G p.L60= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs768521520, COSV52902162; called by muse, mutect2, varscan2
- GLIPR1L1 | c.9G>A p.L3= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV56884210; called by muse, mutect2, varscan2
- GTPBP3 | c.624C>T p.F208= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV50201682; called by muse, mutect2, varscan2
- H1-2 | c.465G>A p.P155= | Silent (SNP) | VAF 63/90 reads (70%) | catalogued as COSV59191887; called by muse, mutect2, varscan2
- HDGFL3 | c.45C>G p.V15= | Silent (SNP) | VAF 6/8 reads (75%) | catalogued as COSV100220926; called by muse, mutect2, varscan2
- HDLBP | c.3577C>T p.L1193= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV51480029; called by muse, mutect2, varscan2
- HEY1 | c.546C>G p.T182= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV61233809; called by muse, mutect2, varscan2
- HIRA | c.1590A>G p.A530= | Silent (SNP) | VAF 80/129 reads (62%) | catalogued as COSV54280549; called by muse, mutect2, varscan2
- IGHV4-39 | c.51G>A p.L17= | Silent (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- INPP1 | c.333C>G p.L111= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV59417802; called by muse, mutect2, varscan2
- IPCEF1 | c.897C>A p.I299= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV99500438; called by muse, mutect2
- KCND1 | c.1761G>A p.L587= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV99502128; called by muse, mutect2, varscan2
- KCNH2 | c.1950C>A p.L650= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV51234597; called by muse, mutect2, varscan2
- KCNQ4 | c.906C>G p.G302= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV61276069; called by muse, mutect2, varscan2
- KLF10 | c.1311G>A p.R437= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV53436966; called by muse, mutect2
- KNSTRN | c.177G>A p.E59= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV51105977, COSV51112613; called by muse, mutect2, varscan2
- KRT79 | c.363G>A p.Q121= | Silent (SNP) | VAF 41/72 reads (57%) | catalogued as COSV100398220, COSV57942573; called by muse, mutect2, varscan2
- L3MBTL4 | c.27G>A p.K9= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as rs754751279, COSV53142684; called by muse, mutect2, varscan2
- LCK | c.1072C>A p.R358= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV60743034; called by muse, mutect2, varscan2
- LPCAT3 | c.1116C>T p.L372= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as COSV54644069; called by muse, mutect2, varscan2
- MDFIC | c.540G>A p.L180= | Silent (SNP) | VAF 128/248 reads (52%) | catalogued as COSV57568029; called by muse, mutect2, varscan2
- MED1 | c.3189C>T p.I1063= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV56128917; called by muse, mutect2, varscan2
- MINK1 | c.3888C>G p.L1296= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99545341; called by muse, mutect2
- MYO15A | c.8541C>T p.F2847= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV52767446; called by muse, mutect2, varscan2
- MYO19 | c.1581C>T p.F527= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- NAGS | c.93G>C p.L31= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs771999272, COSV99517983; called by muse, varscan2
- NAPSA | c.210C>G p.L70= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV53799300; called by muse, mutect2
- NCF2 | c.1083G>C p.T361= | Silent (SNP) | VAF 13/199 reads (7%) | catalogued as COSV62316877; called by muse, mutect2
- NIBAN1 | c.903G>C p.L301= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV62288150; called by muse, mutect2, varscan2
- NLRP13 | c.3111C>T p.C1037= | Silent (SNP) | VAF 146/194 reads (75%) | catalogued as COSV61624307; called by muse, mutect2, varscan2
- NLRP4 | c.793C>T p.L265= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV56724606; called by muse, mutect2, varscan2
- NPC1L1 | c.3783C>T p.L1261= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV56930942; called by muse, mutect2, varscan2
- OR10A2 | c.309T>A p.A103= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV56300704; called by muse, mutect2, varscan2
- OR6Y1 | c.117C>A p.T39= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV56931546; called by muse, mutect2, varscan2
- PCDH10 | c.2559C>T p.C853= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV52096363, COSV52105209; called by muse, mutect2, varscan2
- PDE6C | c.2475C>T p.V825= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV63274072; called by muse, mutect2, varscan2
- PLG | c.807T>A p.S269= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV51982657; called by muse, mutect2, varscan2
- POLR3A | c.426G>A p.L142= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV64932256; called by muse, mutect2, varscan2
- POU6F2 | c.1119C>A p.P373= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV68883320; called by muse, mutect2, varscan2
- PURA | c.351C>T p.F117= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs780978504, COSV100495794; called by muse, varscan2
- RANGAP1 | c.1491G>A p.L497= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV62364905; called by muse, mutect2, varscan2
- RBFOX1 | c.864C>A p.P288= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1348390342, COSV100303529, COSV60970636; called by muse, mutect2
- RIMBP2 | c.780G>A p.E260= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV55485553; called by muse, mutect2
- RNF13 | c.444C>T p.V148= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV60136276; called by muse, mutect2
- RORB | c.231A>G p.R77= (on ENST00000396204 / NM_001365023.1; = p.R66= on NM_006914.4) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV65340493; called by muse, varscan2
- RRBP1 | c.3258G>T p.L1086= (on ENST00000377813 / NM_001365613.2; = p.L653= on NM_004587.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV55709448; called by muse, mutect2, varscan2
- RYK | c.1236G>T p.V412= (on ENST00000620660 / NM_001005861.2; = p.V409= on NM_002958.4) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV56064711; called by muse, mutect2, varscan2
- SDF4 | c.447C>T p.H149= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs752147587, COSV55421984; called by mutect2, varscan2
- SEZ6 | c.1368C>T p.H456= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV57977711; called by muse, mutect2, varscan2
- SFI1 | c.996G>A p.R332= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV101192295; called by muse, mutect2
- SIGLEC11 | c.417G>T p.V139= | Silent (SNP) | VAF 39/51 reads (76%) | catalogued as COSV70221961, COSV70222051, COSV70222200; called by muse, mutect2, varscan2
- SNRK | c.1065C>T p.I355= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV56071235; called by muse, mutect2, varscan2
- SORCS3 | c.3546C>T p.L1182= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100865686, COSV63819426; called by muse, mutect2, varscan2
- SQOR | c.765C>A p.L255= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV52943785, COSV99526247; called by muse, mutect2, varscan2
- STYXL1 | c.369C>T p.P123= | Silent (SNP) | VAF 102/213 reads (48%) | catalogued as rs782122922, COSV50389912; called by muse, mutect2, varscan2
- SVIL | c.3045G>A p.P1015= (on ENST00000355867 / NM_021738.3; = p.P589= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs573451026, COSV63439632; called by muse, mutect2, varscan2
- SYNJ2 | c.2913G>A p.L971= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs748293946, COSV62901199; called by muse, mutect2, varscan2
- TAF1C | c.690C>G p.V230= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV58989689; called by muse, mutect2, varscan2
- TAF6 | c.666C>G p.L222= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs754251564, COSV59844255; called by muse, mutect2, varscan2
- TBC1D1 | c.495C>T p.F165= | Silent (SNP) | VAF 57/110 reads (52%) | catalogued as COSV54728197; called by muse, mutect2, varscan2
- TBC1D1 | c.609C>G p.V203= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV54728207; called by muse, mutect2, varscan2
- TBP | c.9G>A p.Q3= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV51532117; called by muse, mutect2, varscan2
- TCTN2 | c.633C>G p.V211= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as rs569266771, COSV57635288; called by muse, mutect2
- THNSL1 | c.372A>T p.A124= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV64480021; called by muse, mutect2, varscan2
- TPX2 | c.786C>T p.F262= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV55919521, COSV55923288; called by muse, mutect2
- TRAV8-7 | c.78C>T p.G26= | Silent (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- TREM2 | c.681G>A p.L227= | Silent (SNP) | VAF 81/104 reads (78%) | catalogued as COSV58295920; called by muse, mutect2, varscan2
- TTN | c.9534C>T p.H3178= (on ENST00000591111; = p.H3132= on NM_003319.4) | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV60384354; called by muse, mutect2, varscan2
- UBN1 | c.1344C>G p.L448= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV52173585; called by mutect2, varscan2
- WDR6 | c.2484C>T p.L828= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs185020085, COSV58247762; called by muse, mutect2, varscan2
- WSCD2 | c.834C>T p.T278= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs367855700, COSV54590449; called by mutect2, varscan2
- ZNF135 | c.528A>G p.P176= (on ENST00000313434 / NM_001289401.2; = p.P188= on NM_003436.4) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV57886421; called by muse, mutect2, varscan2
- ZNF189 | c.195T>A p.T65= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99407308; called by muse, mutect2
- ZNF366 | c.1785G>A p.Q595= | Silent (SNP) | VAF 44/55 reads (80%) | catalogued as COSV59214793, COSV59219456; called by muse, mutect2, varscan2
- ZNF513 | c.1092C>T p.L364= | Silent (SNP) | VAF 76/143 reads (53%) | catalogued as COSV52011107; called by muse, mutect2, varscan2
- ZXDB | c.597C>G p.A199= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs779074573, COSV100886048; called by muse, varscan2
- HERC2P3 | n.111T>G | RNA (SNP) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- PLEC | c.524-5153C>T | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as COSV59714228; called by muse, mutect2
- POM121 | chr7:72948534 C>G | 3'Flank (SNP) | VAF 49/111 reads (44%) | catalogued as rs782376226, COSV99989202; called by muse, mutect2, varscan2
- POM121 | chr7:72948904 G>C | 3'Flank (SNP) | VAF 8/41 reads (20%) | catalogued as rs369389490, COSV99989203; called by muse, mutect2, varscan2
- PTPDC1 | c.83-673C>T | Intron (SNP) | VAF 38/52 reads (73%) | catalogued as COSV56626882; called by muse, mutect2, varscan2
- RMND5A | c.*2G>C | 3'UTR (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99373938; called by muse, mutect2, varscan2
- SNORD114-27 | n.59T>C | RNA (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- TMPRSS11F | c.1015+1744C>T | Intron (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100678804; called by muse, mutect2, varscan2
- ZNF783 | c.802+3258G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as COSV65187025; called by muse, mutect2, varscan2
